TCGA case TCGA-VQ-A8E7 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Barretos Cancer Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7da1a098-73f7-40c1-8c9d-e0423c15009c

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: Brazil; Age at index: 59 years; Vital status: Alive.

Diagnoses (2)
1. Tubular adenocarcinoma (the primary disease): ICD-O-3 morphology code: 8211/3; ICD-10 code: C16.0; Tissue or organ of origin: Cardia, NOS; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 59.3 years (21,664 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,138 days (3.1 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 23.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Tubular adenocarcinoma), site: Adrenal gland, NOS. Age at diagnosis: 62.2 years (22,712 days); Days to diagnosis: 1,048 days (2.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS to Distant Site.

Follow-up (3 entries)
- Days to follow up: 787 days (2.2 years); Disease response: With Tumor.
- Day 1,048 (post initial treatment): Disease response: With Tumor; Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Adrenal gland, NOS; Days to progression: 1,048 days (2.9 years).
- Days to follow up: 1,138 days (3.1 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VQ-A8E7-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 120 mg.
  Slide TCGA-VQ-A8E7-01B-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 60; Percent normal cells: 30; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-VQ-A8E7-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-VQ-A8E7-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Intestinal Adenocarcinoma, Tubular Type; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Anatomic organ subdivision: Gastroesophageal Junction; Lymph nodes examined: Yes; Tumor sample procurement country: Sao Paulo; Cancer procurement city: Barretos; History reflux disease indicator: No; Antireflux treatment: No; History barretts esophageal indicator: No; History hpylori infection indicator: No; Treatment outcome first course: Stable Disease.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome first course: Stable Disease; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome first course: Stable Disease; Treatment outcome at TCGA followup: Stable Disease.
- Follow-up form 3: Lost to follow-up: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No; New tumor event site other: Adrenal; Treatment outcome first course: Stable Disease.
- Follow-up form 3, New neoplasm event types: New tumor event type: Distant Metastasis.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,138 days; disease-specific survival: no event (censored), 1,138 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,048 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-VQ-A8E7-01B-11D-A40Z-01): tumor purity 0.66, ploidy 2.06, whole-genome doublings 0.
